Somatic mutation profile of tumor specimen TARGET-10-PAUAJA-09A (aliquot TARGET-10-PAUAJA-09A-01D) from TARGET case TARGET-10-PAUAJA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,343 days).
Specimen TARGET-10-PAUAJA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26b44307-28f0-4990-97d2-2c9e526a5c36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUAJA-10A (Blood Derived Normal), aliquot TARGET-10-PAUAJA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ee03bba-536f-4487-a149-cc8eacfb11b9

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Silent 3, 3'UTR 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 47/89 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- BCAR1 | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs774853836, COSV50795296; called by muse, mutect2, varscan2
- GPM6A | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771568010, COSV54559629; called by muse, mutect2, varscan2
- GREB1 | c.3841G>A p.A1281T | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as rs529482867, COSV52189569; called by muse, mutect2, varscan2
- KLK13 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs150383488; called by muse, mutect2, varscan2
- MYB | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV57201468; called by muse, mutect2, varscan2
- POM121L12 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV101374888, COSV68692878; called by muse, mutect2, varscan2
- TLE6 | c.481G>A p.E161K (on ENST00000246112 / NM_001143986.2; = p.E38K on NM_024760.3) | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs906514054; called by muse, mutect2
- TMEM94 | c.1176dup p.T393Dfs*55 | Frame Shift Ins (INS) | VAF 65/97 reads (67%) | catalogued as rs746649748; called by mutect2, pindel, varscan2
- TNXB | c.6055C>T p.R2019C (on ENST00000647633; = p.R1772C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs540179287, COSV64488127; called by muse, mutect2, varscan2
- MEF2C | c.1049G>T p.W350L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- C5 | c.3363T>C p.N1121= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- IGLV4-69 | c.81G>A p.S27= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs1269052294; called by muse, mutect2, varscan2
- TMEM198 | c.978C>T p.T326= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs780003867; called by muse, mutect2, varscan2
- C17orf49 | c.219-37A>G | Intron (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- CD36 | c.1254+61G>A | Intron (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- EED | c.1125+37T>A | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- PIP | c.*49C>T | 3'UTR (SNP) | VAF 65/74 reads (88%) | called by muse, mutect2, varscan2
- PSG3 | c.*197A>T | 3'UTR (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2
- RAB5B | c.532+103dup | Intron (INS) | VAF 18/42 reads (43%) | called by mutect2, varscan2
- RARRES2P9 | n.442G>A | RNA (SNP) | VAF 23/58 reads (40%) | catalogued as rs371005780; called by muse, mutect2, varscan2
